Gene-level copy-number profile of tumor specimen ALCH-AEL7-TTP1-A from ALCHEMIST case ALCH-AEL7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.3 years (19,110 days).
Specimen ALCH-AEL7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d6b6f8c-54fd-49de-9d83-af770db1c3ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEL7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,259 have no estimate.
https://portal.gdc.cancer.gov/files/d8bd9ea4-c2c2-4810-bd5e-ac9a4d1043ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 445; copy number 1: 18,478; copy number 2: 34,873; copy number 3: 3,716; copy number 4: 473; copy number 5: 89; copy number 6: 106; copy number 7: 57; copy number 8: 80; copy number 9: 11; copy number 14: 1; copy number 17: 22; copy number 22: 13.

Homozygous deletions (total copy number 0; autosomes only): 445 genes in 114 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–3,611,508, 32 genes: PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A.
- chr2:131,361,111–131,410,050, 16 genes: RAB6D, AC073869.3, MTCYBP10, MTND6P10, MTND5P23, MTND4P21, AC073869.4, MTCO3P18, MTATP6P4, MTCO2P18, MTCO1P18, MTND2P18, MTND1P26, MED15P3, AC073869.2, LINC01120.
- chr3:8,619,400–8,841,808, 4 genes (within-gene range 0–1): SSUH2, OR7E122P, CAV3, OXTR.
- chr4:181,064,089–182,145,249, 8 genes (within-gene range 0–1): LINC00290, AC019235.1, LINC02500, AC093840.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.
- chr4:189,193,100–189,661,486, 4 genes: AC107391.1, AC105924.1, HSP90AA4P, LINC01262.
- chr7:132,086,266–132,648,688, 4 genes: AC105443.1, PLXNA4, AC018643.1, AC011625.1.
- chr8:264,315–1,731,452, 18 genes: AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, DLGAP2-AS1, AC100810.2.
- chr8:1,763,888–2,838,823, 19 genes (within-gene range 0–2): AC019257.8, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr8:5,848,697–6,257,537, 4 genes: AC087369.1, RN7SKP159, AC079054.1, AC009435.1.
- chr8:6,835,535–7,143,841, 21 genes (within-gene range 0–1): GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P, DEFA1, DEFT1P, DEFA1B, DEFT1P2, DEFA3, DEFA11P, DEFA7P, DEFA5, AF238378.1, AF228730.2, RPS3AP30, SNRPCP6.
- chr8:10,336,782–11,201,833, 28 genes (within-gene range 0–1): AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1.
- chr8:11,247,626–11,285,068, 4 genes (within-gene range 0–1): LINC00529, RPL19P13, AF131216.2, AF131216.4.
- chr8:11,486,894–11,760,002, 4 genes (within-gene range 0–1): BLK, AC022239.1, LINC00208, GATA4.
- chr8:12,676,035–12,818,291, 10 genes: AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681.
- chr8:20,934,435–21,812,357, 11 genes: TMEM97P2, AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153, AC103719.1, AC021613.2, AC021355.1, GFRA2, OR6R2P.
- chr8:23,702,451–23,806,377, 5 genes: NKX2-6, AC012574.1, AC012574.2, AC012119.2, AC012119.1.
- chr8:27,869,883–27,992,673, 5 genes: SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2.
- chr8:31,639,222–32,855,666, 7 genes (within-gene range 0–1): NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1.
- chr8:36,277,763–36,321,404, 6 genes: MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:37,626,015–37,779,768, 8 genes: AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP.
- chr8:40,900,016–41,309,473, 7 genes: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr8:41,566,858–41,896,762, 11 genes: AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P.
- chr8:48,657,260–49,229,174, 7 genes (within-gene range 0–1): AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1.
- chr8:62,191,088–63,014,000, 7 genes (within-gene range 0–1): AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P.
- chr8:63,384,839–63,589,408, 4 genes: AC011124.1, IFITM8P, AC011124.2, AC018953.1.
- chr9:87,799,501–87,859,599, 7 genes: AL772337.4, FBP2P1, ELF2P3, NPAP1P7, CTSLP8, AL772337.2, AL772337.1.
- chr10:129,768,844–130,505,201, 14 genes: AL157832.1, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA.
- chr10:131,092,391–131,795,277, 4 genes: TCERG1L, TCERG1L-AS1, LINC01164, AL450307.1.
- chr10:132,943,967–132,976,354, 3 genes: LINC01166, LINC01167, LINC01168.
- chr12:4,809,176–5,046,788, 6 genes (within-gene range 0–1): KCNA6, AC006063.1, AC005906.2, KCNA1, AC005906.1, KCNA5.
- chr12:128,086,621–128,244,573, 4 genes: LINC02369, LINC02368, AC061709.2, AC061709.1.
- chr12:130,138,693–130,372,637, 8 genes: AC026336.3, FZD10-AS1, AC026336.5, FZD10, AC026336.1, AC026336.2, PIWIL1, AC127071.2.
- chr13:111,588,201–111,901,264, 3 genes: AL359649.1, LINC02337, LINC00354.
- chr15:77,641,764–77,788,674, 3 genes (within-gene range 0–1): LINGO1-AS1, LINGO1-AS2, AC105133.1.
- chr15:87,859,751–88,271,066, 3 genes: NTRK3, MED28P6, NTRK3-AS1.
- chr17:6,207,163–6,556,555, 7 genes: RNU6-1264P, BTF3P14, AIPL1, AC055872.1, PIMREG, PITPNM3, Metazoa_SRP.
- chr17:10,383,132–10,659,082, 9 genes: AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1.
- chr17:17,810,399–17,837,011, 3 genes (within-gene range 0–1): SREBF1, MIR6777, MIR33B.
- chr17:18,950,345–19,047,011, 6 genes (within-gene range 0–1): SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1.
- chr17:19,678,288–19,738,542, 3 genes (within-gene range 0–2): SLC47A2, AC005722.3, AC005722.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 379 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:32,221,932–32,222,347, 1 gene, copy number 5: AC025181.1.
- chr6:27,324,894–27,811,300, 21 genes, copy number 5–7: VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P, RPL8P1, LINC01012, GPR89P, RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10.
- chr6:30,688,047–30,744,548, 10 genes, copy number 9: NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3.
- chr6:30,751,038–30,751,289, 1 gene, copy number 9: RN7SL353P.
- chr6:33,891,327–34,715,940, 23 genes, copy number 5–6 (within-gene range 2–6): AL138889.1, MIR7159, MIR1275, GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1.
- chr6:35,213,956–35,321,771, 5 genes, copy number 5–7: SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6.
- chr6:38,168,451–39,030,792, 13 genes, copy number 6: BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1.
- chr6:42,155,406–43,305,538, 40 genes, copy number 5–8 (within-gene range 3–8): AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1, UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7.
- chr7:54,542,325–55,344,958, 14 genes, copy number 14–22: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr7:55,436,056–55,588,336, 2 genes, copy number 5: VOPP1, AC099681.1.
- chr7:55,876,738–55,955,239, 4 genes, copy number 5 (within-gene range 4–5): AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr7:55,951,877–55,956,500, 1 gene, copy number 5 (within-gene range 4–5): MRPS17.
- chr7:74,606,913–74,633,884, 2 genes, copy number 5: AC211433.2, AC211433.3.
- chr8:81,149,107–81,165,266, 1 gene, copy number 5: AC079209.1.
- chr8:98,944,403–99,013,743, 4 genes, copy number 5 (within-gene range 3–5): OSR2, VPS13B-DT, AC016877.1, AC104986.1.
- chr12:57,723,761–57,742,157, 1 gene, copy number 17 (within-gene range 3–17): AGAP2.
- chr12:57,738,013–57,968,399, 21 genes, copy number 17: TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1.
- chr14:28,264,390–30,297,043, 29 genes, copy number 5–6: BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1.
- chr14:30,559,158–40,390,547, 172 genes, copy number 5–8 (within-gene range 3–9) (broad region; genes not listed).
- chr14:42,807,378–42,808,112, 1 gene, copy number 5: YWHAQP1.
- chr14:43,274,824–43,596,683, 5 genes, copy number 5: TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P.
- chr17:46,503,946–46,509,339, 1 gene, copy number 6: RDM1P2.
- chr17:64,747,264–64,762,710, 4 genes, copy number 5: MICOS10P2, KPNA2P3, AC132812.1, BPTFP1.
- chr20:47,391,925–47,412,327, 1 gene, copy number 5: LINC01754.
- chr21:13,038,160–13,067,033, 2 genes, copy number 5: ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 17,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
